Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3492, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3492-01A (Primary Tumor).

Diagnosis/Diagnoses:

Right hemicolectomy specimen with tumor-free resection margins, including a small tubular and a larger tubulovillous adenoma with moderate dysplasia, with an ulcerated, poorly differentiated adenocarcinoma with infiltration of the perimuscular fat tissue (G3, pT3) and a moderately differentiated adenocarcinoma with infiltration of the submucosa (G2, pT1) in the proximal large bowel and with a detectable ulcer in the aboral section of the preparation, evidently with status post complete endoscopic excision of a tubulovillous adenoma with severe dysplasia (cf. most recent preliminary findings). Tumor-free oral and aboral resection margins. Unremarkable appendix. Tumor-free omental tissue

A follow-up report will be made on the lymph node status.

Follow-up report:

Only twenty-one lymph nodes of up to 0.4 cm in size in the vicinity of the tumor were dissected out from the pericolic fatty tissue after clarification with acetone.

Microscopically these were all tumor-free.

In conclusion, the previously diagnosed double carcinoma of the right colon can be assigned to category pN0 (0/12).

Source: NCI Genomic Data Commons file 7b704dc9-99c5-4e62-b550-77a227bee273 (TCGA-AA-3492.7C11BB51-9AAB-4D92-848D-C10DE65EFBF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).